Gene-level copy-number profile of tumor specimen ALCH-B1UQ-TTP1-A from ALCHEMIST case ALCH-B1UQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.6 years (22,868 days).
Specimen ALCH-B1UQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4a48f2e2-9bd8-417b-bd9d-c8dde6dc5b0d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1UQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/ef8e39ae-7a83-48ee-aa0d-25ea51cbc470

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 121; copy number 1: 12,343; copy number 2: 36,671; copy number 3: 7,899; copy number 4: 1,318; copy number 5: 108; copy number 6: 7; copy number 7: 28; copy number 8: 104; copy number 9: 4; copy number 10: 19; copy number 11: 3; copy number 12: 15; copy number 13: 5; copy number 15: 117; copy number 16: 15; copy number 17: 18; copy number 18: 16; copy number 19: 2; copy number 20: 67; copy number 22: 1; copy number 26: 8; copy number 27: 1; copy number 39: 4.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,495,338–52,524,495, 1 gene (within-gene range 0–2): STAB1.
- chr7:98,211,439–98,252,232, 2 genes: BHLHA15, TECPR1.
- chr7:142,656,701–142,667,718, 2 genes: TRBV24-1, MTRNR2L6.
- chr9:124,853,417–124,861,981, 2 genes: WDR38, RPL35.
- chr11:64,823,052–64,844,653, 1 gene: CDC42BPG.
- chr12:55,113,077–55,124,120, 2 genes: OR9K1P, AC027287.1.
- chr14:99,481,169–99,727,301, 8 genes: CCNK, CCDC85C, AL110504.1, Y_RNA, AL160313.1, HHIPL1, CYP46A1, AL160313.2.
- chr15:21,293,653–21,295,201, 1 gene: AC068446.1.
- chr15:25,180,497–25,250,940, 39 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,774,434–41,894,053, 8 genes (within-gene range 0–3): MAPKBP1, AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr16:67,277,510–67,289,499, 1 gene (within-gene range 0–3): PLEKHG4.
- chr17:18,943,999–19,022,595, 5 genes (within-gene range 0–1): AC090286.2, SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr17:21,259,968–22,288,301, 26 genes: EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2.
- chr19:6,894,994–6,898,686, 2 genes (within-gene range 0–1): AC020895.2, AC020895.1.
- chr19:16,907,462–16,910,784, 2 genes (within-gene range 0–1): RN7SL835P, RN7SL823P.
- chr22:18,715,815–18,719,341, 1 gene: PPP1R26P4.
- chr22:23,786,931–23,839,128, 2 genes: SMARCB1, DERL3.
- chr22:42,126,499–42,132,998, 2 genes (within-gene range 0–2): CYP2D6, AC254562.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 539 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:225,401,502–225,428,925, 1 gene, copy number 5: LBR.
- chr7:37,032–37,477, 1 gene, copy number 5: AC215522.1.
- chr7:9,614,978–9,615,985, 1 gene, copy number 15: GAPDHP68.
- chr7:9,634,270–9,635,703, 1 gene, copy number 15: PER3P1.
- chr7:19,020,991–26,647,305, 117 genes, copy number 10–18 (broad region; genes not listed).
- chr7:27,023,737–27,024,907, 1 gene, copy number 16: TPM3P4.
- chr7:37,585,500–44,069,456, 115 genes, copy number 5–8 (within-gene range 5–14) (broad region; genes not listed).
- chr7:77,122,434–86,217,733, 76 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:146,116,002–148,420,998, 10 genes, copy number 7 (within-gene range 4–7): CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2, RNU6-1184P.
- chr11:49,145,092–49,208,638, 1 gene, copy number 5: FOLH1.
- chr12:64,264,762–64,390,758, 1 gene, copy number 7 (within-gene range 2–11): C12orf56.
- chr12:64,338,178–71,835,396, 163 genes, copy number 7–27 (within-gene range 2–27) (broad region; genes not listed).
- chr12:72,087,266–72,728,844, 5 genes, copy number 12–22 (within-gene range 1–22): TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr12:80,707,634–80,937,925, 7 genes, copy number 11–13 (within-gene range 2–13): MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618.
- chr12:89,319,364–89,319,649, 1 gene, copy number 16: MRPS6P4.
- chr14:18,333,726–18,419,273, 4 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:21,298,233–21,325,241, 2 genes, copy number 19 (within-gene range 4–19): AC068446.2, RNU6-1235P.
- chr15:21,927,657–21,981,245, 3 genes, copy number 6–13: NF1P2, MIR5701-3, OR11J6P.
- chr16:2,339,150–2,426,699, 1 gene, copy number 5 (within-gene range 2–5): ABCA17P.
- chr20:62,872,250–62,948,475, 4 genes, copy number 5: ARF4P2, DIDO1, AL117379.1, GID8.
- chr21:10,413,477–13,120,807, 12 genes, copy number 5 (within-gene range 5–6): BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:15,282,557–15,304,556, 3 genes, copy number 5: AP000542.3, AP000542.1, AP000542.2.
- chr22:15,528,192–15,573,265, 2 genes, copy number 5–12: OR11H1, AP000533.1.
- chr22:18,605,355–18,653,617, 7 genes, copy number 9–39: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 9,783. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
